Surgical pathology report (de-identified scan), TCGA case TCGA-G9-7525, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-7525-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

SPECIMEN(S):

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

DIAGNOSIS:

- A. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4+3 (7/10), INVOLVING ABOUT 10% OF PROSTATE VOLUME, PRESENT IN BOTH LOBES AND WITH FOCAL EXTRAPROSTATIC EXTENSION
- SEMINAL VESICLES AND VAS DEFERENS, NO TUMOR SEEN
- SURGICAL RESECTION MARGINS NEGATIVE FOR TUMOR
- SEE SYNOPSIS REPORT.
- B. LYMPH NODES, RIGHT PELVIC, EXCISION:
- FOUR LYMPH NODES, NEGATIVE FOR METASTASES (0/4)
- C. LYMPH NODES, LEFT PELVIC, EXCISION:
- TWO LYMPH NODES, NEGATIVE FOR METASTASES (0/2)

SYNOPSIS REPORT - PROSTATE GLAND

Location: Left
Right
Posterior lateral
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 10%
Gleason Grade/Sum:: Grade 4 + 3 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: focal at left posterior
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: Negative Right 0 / 4 Left 0 / 2
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 2c N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pT2c: Tumor involves both lobes
pMX: Cannot be assessed

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is an intact prostatectomy specimen weighing 59 g and measuring 5.5 cm from right to left, 4.4 cm from anterior to posterior, and 4.2 cm from apex to base. The capsule is smooth and red. Ink code: Apex-red, anterior-orange, posterior-black, base-blue, right lateral-green, left lateral-yellow. The apex and base are removed from the specimen to yield a new weight of 40g. The specimen is serially sectioned from apex to base to reveal a yellow-tan ill-defined mass in the left lateral portion of the specimen, 2.2 x 1.8 x 1.5

[page 2 of 2]
cm approaching the at distance of 0.2 cm. The right and left seminal vesicles, 2.3 x 1.4 x 0.3, and 2.4 x 1.2 x 0.3 cm, respectively, are bisected to show beige tan cystic tissue. The right and left vas deferens, 3 x 0.5, and 3.1 x 0.4 cm, respectively, are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder entirely submitted:

A1-A2: Right Apex

A3-A4: Left apex

A5: Level I, right anterior

A6: Level I, right posterior

A7: Level I, left anterior

A8: Level I, left posterior

A9-A11: Level II, capsule, right side

A12-A15: Level II, capsule, left side

A16-A17: Right lateral base

A19-A21: Right base

A22: Right base with proximal urethral margin

A23: Left base with proximal urethral margin

A24-A26: Left base

A27-A28: Left lateral base

A29: Representative section (s) right seminal vesicle, right vas deferens

A30: Representative section (s) left seminal vesicle, left vas deferens

B. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and designated "right pelvic lymph nodes" is a fragment of fibroadipose tissue measuring 7.4 x 1.8 x 0.3 CM. Two possible lymph nodes identified measuring 1.8 by a 0.9 x 0.3 cm in aggregate. Cassettes are submitted as follows:

B1: 2 lymph nodes

B2-B3: Remainder of the specimen

C. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and designated "left pelvic lymph nodes" are multiple fragments of fibroadipose tissue measuring 4.3 x 3 x 0.6 cm in aggregate. Two possible lymph nodes identified measuring 2.1 x 2 x 0.4 cm in aggregate. Cassettes are submitted as follows:

C1: 2 possible lymph nodes

C2: Remainder of the specimen

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Carcinoma, prostate

Gross Dictation:., [REDACTED]

Microscopic/Diagnostic Dictation:., [REDACTED]

Final Review: M.D., Pathologist, [REDACTED]

Final:., M.D., Pathologist, [REDACTED]

Source: NCI Genomic Data Commons file e6e63ad0-9283-4167-b22b-1fb29536d8c0 (TCGA-G9-7525.837A5284-61EC-4A13-9743-010FC6A8DF6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).